Somatic mutation profile of tumor specimen TCGA-FX-A8OO-01A (aliquot TCGA-FX-A8OO-01A-11D-A36J-09) from TCGA case TCGA-FX-A8OO, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Synovial sarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of thorax; Age at diagnosis: 31.1 years (11,376 days).
Specimen TCGA-FX-A8OO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 76d74ede-725d-4534-ab38-fdfc06d505ea.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FX-A8OO-10A (Blood Derived Normal), aliquot TCGA-FX-A8OO-10A-01D-A36M-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5c82c8e4-b2e4-476d-8ac9-ec731b99b17f

The open-access MAF lists 29 somatic variants for this specimen: 24 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 24, Silent 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KCNJ2 | c.935G>A p.R312H | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786205820, CM136975, COSV99696396; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- ACSL4 | c.1708C>T p.R570C (on ENST00000340800 / NM_022977.2; = p.R529C on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM020684, CM142265, COSV100538603; called by muse, mutect2, varscan2
- ADGRF1 | c.377C>T p.T126M | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs200254260, COSV100982613; called by muse, mutect2, varscan2
- ASPM | c.7251G>T p.R2417S | Missense Mutation (SNP) | VAF 53/77 reads (69%) | SIFT tolerated (0.52); PolyPhen benign (0.349); catalogued as COSV54133580; called by muse, mutect2, varscan2
- BNC2 | c.562A>T p.I188F | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV101033030, COSV101033325; called by muse, mutect2, varscan2
- BTBD11 | c.1682C>T p.A561V (on ENST00000280758 / NM_001018072.2; = p.A98V on NM_001017523.2) | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1368588123, COSV55016681; called by muse, mutect2, varscan2
- CFP | c.581G>A p.G194E | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1248953318, COSV99901466; called by muse, mutect2, varscan2
- CYP11B1 | c.130C>T p.R44C | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs761472886, COSV99455153; called by muse, mutect2, varscan2
- FBN2 | c.1846G>A p.V616I | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.891); catalogued as COSV99327646; called by muse, mutect2, varscan2
- FOXD4L5 | c.824C>T p.A275V | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as rs1351634964, COSV101073162; called by mutect2, varscan2
- FOXD4L6 | c.824C>T p.A275V | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.227); catalogued as rs1408559943; called by mutect2, varscan2
- LUC7L3 | c.1158T>G p.D386E | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.014); catalogued as COSV99536917; called by muse, mutect2, varscan2
- MLC1 | c.398T>C p.L133P | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100286367; called by muse, mutect2, varscan2
- MORC2 | c.2491G>A p.V831M (on ENST00000397641 / NM_001303256.3; = p.V769M on NM_014941.3) | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.997); catalogued as rs1452993249, COSV99309910; called by muse, mutect2, varscan2
- OR5AS1 | c.547C>A p.P183T | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1351853859, COSV100546288, COSV57982204; called by muse, mutect2, varscan2
- PRADC1 | c.395G>C p.S132T | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT tolerated (0.31); PolyPhen benign (0.091); catalogued as COSV57820315, COSV99240253; called by muse, mutect2, varscan2
- RCC1 | c.238G>T p.V80L | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.703); catalogued as COSV100868133; called by muse, mutect2, varscan2
- SF1 | c.92C>T p.T31I | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.042); catalogued as COSV99918341; called by muse, mutect2, varscan2
- STXBP5L | c.1048G>T p.V350L | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99874278; called by muse, mutect2, varscan2
- TAF1 | c.123A>T p.E41D | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.054); catalogued as COSV99335832; called by muse, mutect2, varscan2
- TASOR2 | c.1207G>T p.A403S | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100050531; called by muse, mutect2
- TTN | c.86269C>G p.R28757G (on ENST00000591111; = p.R21333G on NM_003319.4) | Missense Mutation (SNP) | VAF 31/64 reads (48%) | PolyPhen possibly damaging (0.806); catalogued as COSV100605283, COSV100614540; called by muse, mutect2, varscan2
- YEATS2 | c.2706C>G p.I902M | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.862); catalogued as COSV100527838; called by muse, mutect2, varscan2
- ZNF114 | c.195A>T p.K65N | Missense Mutation (SNP) | VAF 38/74 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.558); catalogued as COSV100252039; called by muse, mutect2, varscan2
- ACTN4 | c.462C>T p.A154= | Silent (SNP) | VAF 31/64 reads (48%) | catalogued as COSV99400254; called by muse, mutect2, varscan2
- COIL | c.264A>G p.R88= | Silent (SNP) | VAF 18/34 reads (53%) | catalogued as COSV99538192; called by muse, mutect2, varscan2
- LOXL2 | c.201C>T p.H67= | Silent (SNP) | VAF 34/70 reads (49%) | catalogued as COSV101207908; called by muse, mutect2, varscan2
- LRRFIP2 | c.1881T>C p.N627= | Silent (SNP) | VAF 19/45 reads (42%) | catalogued as rs201693185, COSV99212470; called by muse, mutect2, varscan2
- POU4F3 | c.336C>T p.H112= | Silent (SNP) | VAF 20/37 reads (54%) | catalogued as rs769752455, COSV100047067; called by muse, mutect2, varscan2
